Surgical pathology report (de-identified scan), TCGA case TCGA-AN-A0FY, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site Cureline, specimen TCGA-AN-A0FY-01A (Primary Tumor).

TSS Patient ID:

Case #: DOB: Sex: Female Ethnicity (Race):

Cancer Sample

Diagnosis: Breast Cancer Histological description: Infiltrative ductal carcinoma

Date of Procurement: Anatomic Site: Left Breast Tumor location: Primary

Tissue Specification: Tumor Specimen Matrix: Tissue Specimen Format: Frozen

Container: cryomold Type of Procurement: Radical mastectomy Grade: 3

T Stage: 1c N Stage: 0 M Stage: 0 Treatment: none

Treatment Details: n/a

Normal Sample

Anatomic Site: Blood Sample Type: Normal Type of Procurement: blood draw

Matrix: Blood Specimen Format: frozen Container: tube

Date of Procurement:

ICD-O-3
carcinoma, infiltrating duct, NOS 8500/3
Site: breast, NOS C50.9
hw
10/21/11

clPAA Discrepancy		X
		hw 10/21/11

Source: NCI Genomic Data Commons file 40f1492e-d1da-4bc2-9cd5-5fee8d454e3e (TCGA-AN-A0FY.6C520037-2A9B-41CB-8362-97FFCA2AA6E2.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).